Gene-level copy-number profile of tumor specimen TCGA-G2-A2EJ-01A from TCGA case TCGA-G2-A2EJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 56.5 years (20,649 days).
Specimen TCGA-G2-A2EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.94b41f94-54e6-4050-818f-3e587ffbe24f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G2-A2EJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/91d3cd26-0b62-4c69-8278-c3310fbcbc25

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 3,192; copy number 2: 48,834; copy number 3: 7,714; copy number 4: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G2-A2EJ-01A-11D-A17S-01): tumor purity 0.61, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:133,117,004–133,119,052, 1 gene: AC011755.1.
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr2:186,354,570–186,695,287, 6 genes (within-gene range 0–2): AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1.
- chr2:213,152,970–213,284,205, 4 genes: AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr2:213,758,067–213,758,159, 1 gene: MIR4438.
- chr4:150,422,645–150,423,642, 1 gene: AC092612.1.
- chr4:181,260,442–181,591,969, 3 genes: LINC02500, AC093840.1, AC093840.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,191. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
